Somatic mutation profile of tumor specimen 0DUXPS from CCDI case PBCMBN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.6 years (237 days).
Specimen 0DUXPS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 662ffa68-7c77-4aed-9fed-8058a7f3a130.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUXO0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc67e9d8-d7cb-4803-a2e3-8931a6d2901c

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 2, 5'UTR 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMCX4 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.083); catalogued as rs966739090; called by muse, mutect2
- CHSY1 | c.1891G>C p.D631H | Missense Mutation (SNP) | VAF 229/600 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54254162; called by muse, mutect2, varscan2
- CRTAC1 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 25/478 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780716192; called by muse, mutect2
- GOLGA6L9 | c.1117G>C p.A373P | Missense Mutation (SNP) | VAF 8/250 reads (3%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1348789502; called by muse, mutect2
- SMARCB1 | c.141C>A p.Y47* | Nonsense Mutation (SNP) | VAF 295/310 reads (95%) | catalogued as CM108557, COSV54093088; called by muse, mutect2, varscan2
- MBTD1 | c.1258G>T p.D420Y | Missense Mutation (SNP) | VAF 105/415 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LARP4 | c.1101T>C p.G367= | Silent (SNP) | VAF 13/346 reads (4%) | called by muse, mutect2
- MAGED1 | c.1487-100C>T | Intron (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- MPND | c.7+40_7+41insTTGCAGGGGCGCGGGG | Intron (INS) | VAF 8/224 reads (4%) | called by mutect2, varscan2*
- SEMA3E | c.-94G>T | 5'UTR (SNP) | VAF 50/117 reads (43%) | called by muse, mutect2, varscan2
